Somatic mutation profile of tumor specimen TCGA-C5-A7UI-01A (aliquot TCGA-C5-A7UI-01A-11D-A36J-09) from TCGA case TCGA-C5-A7UI, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G3; Age at diagnosis: 42.0 years (15,349 days).
Specimen TCGA-C5-A7UI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1c8f711-ddbb-4a57-a4b6-5572d352b989.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-C5-A7UI-10B (Blood Derived Normal), aliquot TCGA-C5-A7UI-10B-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca98d586-a7ff-497c-bd8e-22ad96c81888

The open-access MAF lists 126 somatic variants for this specimen: 98 protein-altering or splice-affecting, 27 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 86, Silent 27, Nonsense Mutation 7, Splice Region 2, Frame Shift Del 2, Frame Shift Ins 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK | c.6985G>C p.D2329H | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99945396; called by muse, mutect2, varscan2
- ARHGEF40 | c.3064G>C p.E1022Q | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.26); PolyPhen benign (0.199); catalogued as COSV100069934; called by muse, mutect2, varscan2
- ASCC2 | c.428C>T p.P143L | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs954651084, COSV100315945; called by muse, mutect2, varscan2
- ATP11A | c.2895C>G p.F965L | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.677); catalogued as COSV99367322; called by mutect2, varscan2
- BCCIP | c.247C>G p.L83V | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53394527, COSV99532855; called by muse, mutect2, varscan2
- BMPR2 | c.1413G>A p.L471= | Splice Region (SNP) | VAF 16/80 reads (20%) | catalogued as COSV101001211; called by muse, mutect2, varscan2
- BRINP1 | c.811G>A p.E271K | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0.039); catalogued as rs1444854216, COSV99774274, COSV99775546; called by muse, mutect2, varscan2
- BRINP3 | c.407T>C p.L136S | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100818272; called by mutect2, varscan2
- C12orf50 | c.1136C>T p.T379M | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs189840625, COSV53893594; called by muse, mutect2, varscan2
- CDS2 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100986058; called by muse, mutect2, varscan2
- CLP1 | c.256A>G p.K86E | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV100239688; called by muse, mutect2, varscan2
- CPAMD8 | c.2653T>C p.Y885H (on ENST00000651564; = p.Y838H on NM_015692.5) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV101488382; called by muse, mutect2, varscan2
- CPNE4 | c.1093G>A p.A365T | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs370033923; called by muse, mutect2, varscan2
- CSPP1 | c.1199C>T p.S400F (on ENST00000676605; = p.S359F on NM_024790.6) | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99137985; called by muse, mutect2, varscan2
- CTAGE6 | c.1103C>T p.S368L | Missense Mutation (SNP) | VAF 44/249 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.272); catalogued as COSV69917697; called by muse, mutect2, varscan2
- CYP2C8 | c.374G>A p.R125H | Missense Mutation (SNP) | VAF 38/67 reads (57%) | SIFT deleterious (0.04); PolyPhen benign (0.445); catalogued as rs775342549, COSV100987872; called by muse, mutect2, varscan2
- DNAJA3 | c.1410C>G p.F470L | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV99276389; called by muse, mutect2, varscan2
- DSEL | c.1237G>C p.D413H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV100025205; called by muse, mutect2, varscan2
- DSEL | c.1037G>T p.W346L | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100025206; called by muse, mutect2, varscan2
- EIF4G3 | c.1936C>T p.P646S | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99943087; called by muse, mutect2, varscan2
- FANCM | c.2180G>A p.G727E | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV99950372; called by muse, mutect2, varscan2
- FKBP14 | c.628G>C p.E210Q | Missense Mutation (SNP) | VAF 3/31 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99767031; called by muse, mutect2
- FRMPD1 | c.3808G>C p.E1270Q | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.055); catalogued as COSV100899258; called by muse, mutect2, varscan2
- FZD10 | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99969198, COSV99969663; called by muse, mutect2, varscan2
- GCFC2 | c.2338G>A p.E780K | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.001); catalogued as COSV100319329; called by muse, mutect2, varscan2
- GEMIN4 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT tolerated (0.92); PolyPhen benign (0.007); catalogued as COSV100021169; called by muse, mutect2, varscan2
- GJA10 | c.1584G>C p.W528C | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV101005276; called by muse, mutect2
- HDX | c.143T>C p.V48A | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99946501; called by muse, mutect2, varscan2
- HMCN1 | c.2938C>T p.L980= | Splice Region (SNP) | VAF 27/88 reads (31%) | catalogued as COSV99623630; called by muse, mutect2, varscan2
- HOOK3 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100294994; called by muse, mutect2, varscan2
- HSP90AA1 | c.1013G>C p.R338T | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.72); catalogued as COSV99354985; called by muse, mutect2, varscan2
- IQCC | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99356291; called by muse, mutect2, varscan2
- IQUB | c.1993G>C p.A665P | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.22); PolyPhen benign (0.08); catalogued as COSV100226698; called by muse, mutect2
- ISLR2 | c.296G>A p.S99N | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV100679357; called by muse, mutect2, varscan2
- ITGA2B | c.934C>T p.R312C | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.337); catalogued as COSV99288525; called by muse, mutect2, varscan2
- KCNB1 | c.1963G>A p.E655K | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.852); catalogued as rs769948178, COSV65568188; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KCNC1 | c.1529C>T p.S510L | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV56393131, COSV99788711; called by muse, mutect2, varscan2
- KIFC2 | c.1216C>A p.L406I | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs1237478741, COSV100023447; called by muse, mutect2, varscan2
- KMT2C | c.3327G>A p.W1109* | Nonsense Mutation (SNP) | VAF 30/65 reads (46%) | catalogued as COSV100065969; called by muse, mutect2, varscan2
- KMT2D | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs1057519422, COSV99977211; called by muse, mutect2, varscan2
- KMT2D | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 8/28 reads (29%) | catalogued as COSV99976450, COSV99977213; called by mutect2, varscan2
- LARP6 | c.1273G>A p.V425I | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765085044, COSV100150659; called by muse, mutect2
- MAGEC3 | c.810G>A p.M270I | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1354325551, COSV100024763; called by muse, mutect2, varscan2
- MAGI1 | c.1721C>T p.A574V | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV58333510; called by muse, mutect2, varscan2
- MCPH1 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.169); catalogued as COSV100765213; called by muse, mutect2, varscan2
- MRAS | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 18/56 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.13); catalogued as rs1289566807, COSV56673105; called by muse, mutect2, varscan2
- MTERF3 | c.770G>C p.R257T | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99749527; called by muse, mutect2, varscan2
- MUC3A | c.7918C>A p.Q2640K | Missense Mutation (SNP) | VAF 26/112 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100113861; called by muse, mutect2, varscan2
- MUSK | c.1852G>A p.D618N | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV99503610; called by muse, mutect2, varscan2
- MYEF2 | c.1258G>A p.G420S | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.025); catalogued as COSV99981140; called by muse, mutect2, varscan2
- NAF1 | c.257C>T p.P86L | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as rs1296550785, COSV99918877; called by muse, mutect2
- NEDD9 | c.2414C>T p.T805M | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs762734867, COSV101060751, COSV101060803; called by muse, mutect2, varscan2
- NELFA | c.983C>A p.P328H (on ENST00000542778; = p.P317H on NM_005663.5) | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as COSV100372794; called by muse, mutect2, varscan2
- NLRP8 | c.1054G>A p.V352I | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.085); catalogued as rs201462125; called by muse, mutect2, varscan2
- NMUR1 | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as rs749642766, COSV59404465; called by muse, varscan2
- NTN1 | c.1109A>G p.N370S | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.593); catalogued as rs776977895, COSV99432165; called by muse, mutect2, varscan2
- NUDT17 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 24/96 reads (25%) | catalogued as COSV100492760; called by muse, mutect2, varscan2
- ODC1 | c.355C>G p.Q119E | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs368830902; called by muse, mutect2, varscan2
- OR1L1 | c.85C>G p.Q29E | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV100542078; called by muse, mutect2, varscan2
- OR6C74 | c.695G>T p.R232I | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV100667653; called by muse, mutect2, varscan2
- OR8G1 | c.475C>T p.H159Y | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.248); catalogued as COSV58380070; called by muse, mutect2, varscan2
- PIGH | c.7G>T p.D3Y | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.165); catalogued as COSV99372950; called by muse, varscan2
- PSMD12 | c.1024G>T p.G342C | Missense Mutation (SNP) | VAF 14/101 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.489); catalogued as COSV100635256; called by muse, mutect2, varscan2
- RADX | c.14C>T p.S5L | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.001); catalogued as COSV100998731, COSV65319081; called by muse, mutect2, varscan2
- RAPGEF4 | c.883G>C p.E295Q | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.407); catalogued as COSV99909552; called by muse, mutect2, varscan2
- RBM5 | c.2111G>A p.R704Q | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV100762123; called by muse, mutect2, varscan2
- RIMS3 | c.685G>C p.D229H | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.669); catalogued as COSV101013260; called by muse, mutect2, varscan2
- RPS6KA1 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.894); catalogued as COSV100837884; called by muse, mutect2, varscan2
- RRAGB | c.863G>A p.R288K (on ENST00000262850 / NM_016656.4; = p.R260K on NM_006064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV53329500, COSV99469009; called by muse, mutect2, varscan2
- RSKR | c.461A>T p.E154V | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as COSV99971901; called by muse, mutect2, varscan2
- SACS | c.13235G>C p.R4412T | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV101207154, COSV66543913; called by muse, mutect2, varscan2
- SBF2 | c.301G>T p.E101* | Nonsense Mutation (SNP) | VAF 26/57 reads (46%) | catalogued as COSV99812941; called by muse, mutect2, varscan2
- SEC24D | c.2255C>T p.T752M | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745329490, COSV54876463; called by muse, mutect2, varscan2
- SEMA4A | c.226C>T p.L76F | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100740416; called by muse, mutect2
- SETBP1 | c.476C>G p.S159C | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as COSV99951862; called by muse, mutect2, varscan2
- SLC15A2 | c.1393C>G p.H465D | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT tolerated (0.64); PolyPhen benign (0.001); catalogued as COSV55200948, COSV99815053; called by muse, mutect2, varscan2
- SLC5A7 | c.112C>T p.R38C | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as rs935822553, COSV50901443, COSV50909428; called by muse, mutect2, varscan2
- SMURF1 | c.1400C>T p.T467M | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs1354399014, COSV63157181; called by muse, mutect2, varscan2
- SOX5 | c.1970G>A p.R657Q | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV100505820; called by muse, mutect2, varscan2
- SRRM2 | c.4627C>G p.Q1543E | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.05); catalogued as rs377397683, COSV100070085; called by muse, mutect2, varscan2
- TBPL2 | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs542835695, COSV55973236; called by muse, mutect2, varscan2
- TMED1 | c.138C>G p.F46L | Missense Mutation (SNP) | VAF 16/59 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as rs780438595, COSV99284017; called by muse, mutect2, varscan2
- TMPRSS11F | c.753G>A p.W251* | Nonsense Mutation (SNP) | VAF 18/38 reads (47%) | catalogued as COSV100678114; called by muse, mutect2
- TNKS | c.3978G>C p.K1326N | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs372614885; called by muse, mutect2, varscan2
- TRIOBP | c.343C>G p.L115V | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.17); catalogued as COSV100730567; called by muse, mutect2, varscan2
- TRPC3 | c.1270C>G p.L424V (on ENST00000379645 / NM_001366479.2; = p.L351V on NM_003305.2) | Missense Mutation (SNP) | VAF 3/50 reads (6%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.589); catalogued as COSV99312056; called by muse, mutect2
- TTC5 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV99351539; called by muse, mutect2, varscan2
- UNC79 | c.2702G>C p.R901T (on ENST00000393151 / NM_001346218.2; = p.R724T on NM_020818.5) | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.382); catalogued as COSV99825577; called by muse, mutect2, varscan2
- UNC93A | c.1271C>T p.A424V | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.069); catalogued as rs372785800; called by muse, mutect2, varscan2
- VEZT | c.1642G>A p.D548N | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.395); catalogued as rs750869300, COSV99703414; called by muse, mutect2, varscan2
- ZMYM1 | c.85G>A p.D29N | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.019); catalogued as rs761195432, COSV100720883; called by muse, mutect2, varscan2
- ZNF253 | c.554C>G p.S185* | Nonsense Mutation (SNP) | VAF 23/81 reads (28%) | catalogued as COSV100849436, COSV63036828; called by muse, mutect2, varscan2
- ZNF404 | c.870G>C p.K290N | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV100182252; called by muse, mutect2, varscan2
- AATF | c.1020G>C p.K340N | Missense Mutation (SNP) | VAF 20/48 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- KMT2D | c.15272_15275dup p.C5092* | Nonsense Mutation (INS) | VAF 4/26 reads (15%) | called by mutect2, pindel
- NCKAP1 | c.3307_3308dup p.L1103Ffs*11 | Frame Shift Ins (INS) | VAF 22/96 reads (23%) | called by mutect2, pindel, varscan2
- NRSN1 | c.189+1del | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | called by mutect2, pindel, varscan2
- TRHDE | c.1664_1673del p.T555Sfs*18 | Frame Shift Del (DEL) | VAF 26/129 reads (20%) | called by mutect2, pindel, varscan2
- ALMS1 | c.2460C>T p.F820= | Silent (SNP) | VAF 11/44 reads (25%) | catalogued as COSV100041010; called by muse, mutect2, varscan2
- CCNQ | c.342C>T p.F114= | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV52345809; called by muse, mutect2, varscan2
- DMPK | c.1179G>A p.P393= | Silent (SNP) | VAF 22/80 reads (28%) | catalogued as rs1421630354, COSV99352687; called by muse, mutect2, varscan2
- EEF1E1 | c.48G>C p.L16= | Silent (SNP) | VAF 8/80 reads (10%) | catalogued as COSV101121232; called by muse, mutect2, varscan2
- EPHB4 | c.792G>A p.G264= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as COSV100639394; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1332C>G p.V444= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV100435429, COSV58545818; called by muse, mutect2, varscan2
- GLI1 | c.2251C>T p.L751= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs192168783, COSV57364860, COSV99953633; called by muse, mutect2, varscan2
- GRIA1 | c.1794C>T p.F598= | Silent (SNP) | VAF 21/37 reads (57%) | catalogued as COSV99597911; called by muse, mutect2, varscan2
- HERC2 | c.5628T>G p.G1876= | Silent (SNP) | VAF 23/150 reads (15%) | catalogued as COSV99870615; called by muse, mutect2, varscan2
- ITCH | c.1830C>T p.C610= (on ENST00000262650 / NM_001257137.3; = p.C569= on NM_031483.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as COSV99391909; called by muse, mutect2, varscan2
- KDM8 | c.624G>C p.L208= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as COSV99619190, COSV99619511; called by muse, mutect2, varscan2
- MST1R | c.3843G>A p.L1281= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV99617600; called by muse, mutect2, varscan2
- MTHFD2L | c.345C>T p.L115= (on ENST00000395759 / NM_001144978.2; = p.L57= on NM_001004346.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs1372892627, COSV100305799; called by muse, mutect2, varscan2
- NLGN4X | c.288C>T p.S96= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV99319677; called by muse, mutect2, varscan2
- PBLD | c.711C>T p.L237= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as COSV53266771, COSV99515987; called by muse, mutect2, varscan2
- PIGH | c.6G>A p.E2= | Silent (SNP) | VAF 4/19 reads (21%) | catalogued as rs1474003890, COSV99372952; called by muse, mutect2, varscan2
- PLCB2 | c.3087G>C p.L1029= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV99541452; called by muse, mutect2, varscan2
- PLXNA4 | c.5365C>T p.L1789= | Silent (SNP) | VAF 17/95 reads (18%) | catalogued as COSV100322260; called by muse, mutect2, varscan2
- PTPRC | c.2283G>A p.K761= | Silent (SNP) | VAF 17/51 reads (33%) | catalogued as rs761064149, COSV100722085; called by mutect2, varscan2
- RPS7 | c.6C>T p.F2= | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV100513887; called by muse, mutect2
- SALL3 | c.2250C>T p.N750= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as rs932625576, COSV73306189; called by muse, mutect2, varscan2
- SIN3B | c.600G>A p.T200= | Silent (SNP) | VAF 20/69 reads (29%) | catalogued as rs746957519, COSV56133207; called by muse, mutect2, varscan2
- SLC4A1 | c.2434C>T p.L812= | Silent (SNP) | VAF 9/47 reads (19%) | catalogued as COSV99292944; called by muse, mutect2, varscan2
- SLC7A10 | c.273C>G p.L91= | Silent (SNP) | VAF 26/80 reads (33%) | catalogued as COSV99471954; called by muse, mutect2, varscan2
- SPATA13 | c.1914G>A p.S638= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs767206279, COSV100541925; called by muse, mutect2, varscan2
- SUN1 | c.786G>A p.Q262= (on ENST00000405266 / NM_001367651.1; = p.Q225= on NM_001130965.3 and 17 other RefSeq transcripts) | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV100568504; called by muse, mutect2, varscan2
- USP6 | c.3078G>A p.A1026= | Silent (SNP) | VAF 17/79 reads (22%) | catalogued as rs778943960, COSV51488753; called by muse, mutect2, varscan2
- AL162726.3 | n.255+83124G>A | Intron (SNP) | VAF 32/166 reads (19%) | called by muse, mutect2, varscan2
